Somatic mutation profile of tumor specimen TCGA-92-8064-01F (aliquot TCGA-92-8064-01F-01D-A38P-08) from TCGA case TCGA-92-8064, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 58.6 years (21,417 days).
Specimen TCGA-92-8064-01F: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 229cdd91-a89f-48d9-9061-87982f65e2af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-92-8064-10A (Blood Derived Normal), aliquot TCGA-92-8064-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/340b457a-b7dd-489a-9e14-89a253c08834

The open-access MAF lists 83 somatic variants for this specimen: 70 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 12, Frame Shift Del 4, Nonsense Mutation 4, Splice Site 2, Frame Shift Ins 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 19/164 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519924, COSV67962147; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 19/160 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960135, COSV67960407, COSV67962953; called by muse, mutect2, varscan2
- A2ML1 | c.2704C>A p.L902I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs1195893094; called by muse, mutect2, varscan2
- ADGRE1 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV51678768; called by muse, mutect2
- CCL21 | c.383C>A p.S128* | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | catalogued as rs1370944166; called by muse, mutect2, varscan2
- CDH11 | c.1359G>T p.W453C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51770173, COSV51771651; called by muse, mutect2, varscan2
- CEP170 | c.2764A>G p.S922G | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV100316353; called by muse, mutect2, varscan2
- CLDN16 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs376431300, CM116890; called by muse, mutect2, varscan2
- DGAT2L6 | c.802G>T p.G268C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145712346; called by muse, mutect2, varscan2
- DLAT | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1555179651; called by muse, mutect2, varscan2
- DSCAM | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs755881168, COSV68024346; called by muse, mutect2, varscan2
- ECT2 | c.1519G>T p.D507Y (on ENST00000392692 / NM_001349098.2; = p.D476Y on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1208066079; called by muse, mutect2, varscan2
- ELAVL2 | c.496A>T p.R166W | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56356678; called by muse, mutect2, varscan2
- FLG | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV64249223; called by muse, mutect2, varscan2
- FNTA | c.269T>G p.I90S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100172549; called by mutect2, varscan2
- GP9 | c.184A>C p.S62R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs1267634927; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs1345732673; called by muse, mutect2, varscan2
- ITGAX | c.2198G>T p.R733L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs761201188, COSV51643111; called by muse, mutect2, varscan2
- KDR | c.1157T>C p.M386T | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs949197675, COSV55779451; called by muse, mutect2, varscan2
- KRTAP5-3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/197 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.222); catalogued as COSV101294487; called by muse, mutect2
- LAMC1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99280636; called by muse, mutect2, varscan2
- MYO3A | c.2596G>T p.V866L | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56333440; called by muse, mutect2, varscan2
- NEUROD4 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 48/430 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV54470829; called by muse, mutect2, varscan2
- PAPPA2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs375011994, COSV62779185; called by mutect2, varscan2
- PAQR3 | c.811G>T p.G271* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as rs754070447; called by mutect2, varscan2
- SERINC2 | c.810G>T p.Q270H (on ENST00000373709 / NM_178865.5; = p.Q274H on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101036882; called by muse, mutect2, varscan2
- TAF1L | c.1327A>G p.K443E | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as rs1367392431; called by muse, mutect2, varscan2
- TNKS | c.3805G>T p.A1269S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60067648; called by muse, mutect2
- AIM2 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ATP2C2 | c.2465T>A p.F822Y | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ATP6V0A1 | c.2500A>T p.K834* (on ENST00000343619 / NM_001378531.1; = p.K828* on NM_005177.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/129 reads (12%) | called by muse, mutect2, varscan2
- BRINP2 | c.1967G>C p.S656T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CDH9 | c.1254G>C p.K418N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CNR1 | c.1291T>A p.C431S | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CR1L | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CST11 | c.301A>T p.N101Y | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DGKB | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- DMRTB1 | c.1023_1024del p.D342Lfs*30 | Frame Shift Del (DEL) | VAF 17/163 reads (10%) | called by mutect2, pindel, varscan2
- EBF3 | c.967G>T p.V323F (on ENST00000355311 / NM_001375392.1; = p.V314F on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- EPDR1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM135B | c.2851A>C p.T951P | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- FBXO34 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FRMD3 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2
- GIT1 | c.1920_1921del p.S641Hfs*28 | Frame Shift Del (DEL) | VAF 20/151 reads (13%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.4960G>T p.E1654* | Nonsense Mutation (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- HRNR | c.3280_3281del p.A1094* | Frame Shift Del (DEL) | VAF 20/194 reads (10%) | called by mutect2, varscan2
- KCNQ3 | c.2463T>G p.N821K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LCT | c.3691G>C p.E1231Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MEF2C | c.360T>G p.I120M | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MIPOL1 | c.773T>A p.I258K | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTERF4 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NEB | c.4220A>T p.Q1407L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NOVA1 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR10G8 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR10K1 | c.529T>A p.F177I | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- OR2L3 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- PKP2 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- RC3H1 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAE1 | c.875_878+4del p.X292_splice | Splice Site (DEL) | VAF 11/126 reads (9%) | called by mutect2, pindel
- SERINC2 | c.811G>T p.A271S (on ENST00000373709 / NM_178865.5; = p.A275S on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SLC15A2 | c.37_38del p.L13Ffs*7 | Frame Shift Del (DEL) | VAF 50/240 reads (21%) | called by pindel, varscan2
- SLC25A5 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SPTA1 | c.7091dup p.A2365Gfs*44 | Frame Shift Ins (INS) | VAF 7/73 reads (10%) | called by mutect2, varscan2
- SYNE1 | c.13961T>G p.V4654G (on ENST00000367255 / NM_182961.4; = p.V4583G on NM_033071.3) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TAF1L | c.2309C>A p.P770Q | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- THAP6 | c.14G>T p.C5F | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TRAV10 | c.164G>C p.R55T | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- WDR17 | c.2024C>A p.S675Y | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBBX | c.7A>G p.R3G | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF197 | c.643-1G>A p.X215_splice | Splice Site (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- CCDC171 | c.942T>A p.A314= | Silent (SNP) | VAF 24/143 reads (17%) | called by muse, mutect2, varscan2
- DNAH5 | c.3141G>A p.G1047= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- F5 | c.600G>A p.E200= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV100889203; called by muse, mutect2, varscan2
- OR11H1 | c.925C>T p.L309= | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as COSV99079129; called by mutect2, varscan2
- OR52A5 | c.255C>A p.G85= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.1008A>T p.T336= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- POLR3F | c.816A>T p.A272= | Silent (SNP) | VAF 18/175 reads (10%) | catalogued as rs1470434304; called by muse, mutect2, varscan2
- PTGER3 | c.1125C>A p.P375= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- PTPRD | c.4644G>T p.P1548= | Silent (SNP) | VAF 7/52 reads (13%) | called by mutect2, varscan2
- SEMA3E | c.876C>G p.L292= | Silent (SNP) | VAF 9/72 reads (13%) | called by mutect2, varscan2
- SYT7 | c.879C>T p.L293= | Silent (SNP) | VAF 24/460 reads (5%) | called by muse, mutect2
- TEP1 | c.4068G>A p.K1356= | Silent (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845966 G>A | 5'Flank (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
